Somatic mutation profile of tumor specimen TCGA-31-1953-01A (aliquot TCGA-31-1953-01A-01W-0699-08) from TCGA case TCGA-31-1953, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 52.2 years (19,064 days).
Specimen TCGA-31-1953-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b51d66a-a76b-4720-89f4-fa3a8f78c7cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-31-1953-10A (Blood Derived Normal), aliquot TCGA-31-1953-10A-01W-0699-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10ca1748-3276-42a0-8afe-529858237f2e

The open-access MAF lists 55 somatic variants for this specimen: 47 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 43, Silent 8, Frame Shift Del 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB8 | c.2020C>A p.R674S (on ENST00000297504 / NM_001282291.2; = p.R657S on NM_007188.5) | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV52501969, COSV52511368; called by muse, mutect2, varscan2
- ACO1 | c.2434G>T p.G812C | Missense Mutation (SNP) | VAF 10/290 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100008756; called by muse, mutect2
- ADAMTSL3 | c.4655G>A p.R1552Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772236407, COSV54452658; called by muse, mutect2, varscan2
- ADCY2 | c.214G>T p.V72F | Missense Mutation (SNP) | VAF 70/337 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV57904483; called by muse, mutect2, varscan2
- AL035461.3 | c.2785C>G p.R929G | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.808); catalogued as COSV66652529, COSV66652782; called by muse, mutect2, varscan2
- B3GALT2 | c.1142C>A p.T381N | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100813642; called by muse, mutect2, varscan2
- B3GALT2 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 67/190 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.593); catalogued as rs770824791, COSV66464610; called by muse, mutect2, varscan2
- C6orf136 | c.818G>A p.R273H (on ENST00000376473 / NM_001109938.3; = p.R139H on NM_145029.4) | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.419); catalogued as rs1342203506, COSV99528248; called by muse, mutect2
- CDK12 | c.2156G>A p.W719* | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | catalogued as COSV71003167; called by muse, mutect2, varscan2
- COL6A6 | c.409G>C p.V137L | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV62039638; called by muse, mutect2, varscan2
- CYP2E1 | c.206C>G p.T69R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV53313649, COSV53315767; called by muse, mutect2, varscan2
- DGKH | c.2824A>G p.R942G | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54943487; called by muse, mutect2, varscan2
- DNAH8 | c.9046T>C p.F3016L | Missense Mutation (SNP) | VAF 16/239 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.513); catalogued as COSV100547381; called by muse, mutect2
- E2F7 | c.1832A>T p.K611I | Missense Mutation (SNP) | VAF 116/310 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59744254; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1797G>T p.Q599H (on ENST00000361735 / NM_015935.5; = p.Q513H on NM_014955.3) | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100676078; called by muse, mutect2
- ERGIC3 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.794); catalogued as rs868448649, COSV54135421; called by muse, mutect2
- IL11RA | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs371329032; called by muse, mutect2, varscan2
- KMT2C | c.5429T>G p.L1810W | Missense Mutation (SNP) | VAF 231/1319 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1252594627, COSV51511794; called by muse, mutect2, varscan2
- LDHAL6A | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 31/788 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.338); catalogued as COSV52650076; called by muse, mutect2
- LRRIQ3 | c.1262G>C p.S421T | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV63050990; called by muse, mutect2, varscan2
- MB21D2 | c.494G>C p.C165S | Missense Mutation (SNP) | VAF 37/252 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.966); catalogued as COSV66666474; called by muse, mutect2, varscan2
- MME | c.1466A>G p.N489S | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV64711429; called by muse, mutect2, varscan2
- MTMR1 | c.1348T>A p.S450T | Missense Mutation (SNP) | VAF 57/476 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as COSV64893090; called by muse, mutect2, varscan2
- MYL2 | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 243/512 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs727504405, COSV57406212, COSV57408315; ClinVar: uncertain significance; called by muse, mutect2
- MYRIP | c.2403del p.K802Nfs*7 | Frame Shift Del (DEL) | VAF 79/286 reads (28%) | catalogued as COSV56871836; called by mutect2, pindel, varscan2
- NRXN3 | c.828C>G p.I276M | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV100210030; called by muse, mutect2, varscan2
- NUP160 | c.3403A>G p.I1135V | Missense Mutation (SNP) | VAF 151/341 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.012); catalogued as COSV65856416; called by muse, mutect2, varscan2
- OR10G3 | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100336152; called by muse, mutect2
- OR4C13 | c.109A>G p.M37V | Missense Mutation (SNP) | VAF 148/606 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1281231019, COSV73648973; called by muse, mutect2, varscan2
- PCDHB16 | c.1862A>G p.N621S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.084); catalogued as rs1554282373, COSV53372455; called by muse, mutect2, varscan2
- PDIK1L | c.487C>G p.R163G | Missense Mutation (SNP) | VAF 62/392 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV65322900, COSV65323062; called by muse, mutect2, varscan2
- PLPP4 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as rs766256076, COSV64830002; called by muse, mutect2, varscan2
- PNLIP | c.869G>C p.S290T | Missense Mutation (SNP) | VAF 61/263 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65042210; called by muse, mutect2, varscan2
- RAD23A | c.1074G>C p.Q358H | Missense Mutation (SNP) | VAF 88/184 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV57540092; called by muse, varscan2
- RIMS2 | c.4750T>G p.S1584A (on ENST00000666250 / NM_001348490.2; = p.S1155A on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/655 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV99207182; called by muse, mutect2
- RYK | c.667A>G p.T223A | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV99938622; called by muse, mutect2
- SMC6 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV61173504; called by muse, mutect2
- SPTA1 | c.4342G>T p.G1448W | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs754924226, COSV63760937; called by muse, mutect2, varscan2
- TRIB3 | c.337C>G p.R113G | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.67); catalogued as COSV53933020; called by muse, mutect2, varscan2
- UBE4B | c.488G>C p.C163S | Missense Mutation (SNP) | VAF 21/350 reads (6%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.966); catalogued as COSV53538851, COSV99477851; called by muse, mutect2
- VGLL1 | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.7); catalogued as COSV65703973; called by muse, mutect2, varscan2
- ZFP57 | c.714G>C p.K238N | Missense Mutation (SNP) | VAF 124/214 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65307200; called by muse, mutect2, varscan2
- ZNF445 | c.387G>C p.L129F | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV68539759; called by muse, mutect2, varscan2
- ZNF583 | c.779G>A p.R260K | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV52404987; called by muse, mutect2, varscan2
- CNDP1 | c.18del p.R7Efs*29 | Frame Shift Del (DEL) | VAF 19/137 reads (14%) | called by mutect2, pindel, varscan2
- PLEKHG1 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TP53 | c.291_325del p.Q100Gfs*37 | Frame Shift Del (DEL) | VAF 396/580 reads (68%) | called by mutect2, pindel
- CBLIF | c.25C>T p.L9= | Silent (SNP) | VAF 81/533 reads (15%) | catalogued as COSV57240681; called by muse, mutect2, varscan2
- EXOC6B | c.63C>T p.I21= | Silent (SNP) | VAF 10/244 reads (4%) | catalogued as COSV99726830; called by muse, mutect2
- LPA | c.3603G>A p.Q1201= | Silent (SNP) | VAF 106/153 reads (69%) | catalogued as COSV60314334; called by muse, mutect2, varscan2
- PRELP | c.954C>T p.L318= | Silent (SNP) | VAF 37/231 reads (16%) | catalogued as COSV58117361, COSV58117841; called by muse, mutect2, varscan2
- PROM2 | c.168G>T p.A56= | Silent (SNP) | VAF 20/278 reads (7%) | catalogued as COSV100469464; called by muse, mutect2
- ROCK2 | c.1632A>G p.K544= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as COSV99837981; called by muse, mutect2
- SLAMF6 | c.186T>G p.L62= | Silent (SNP) | VAF 173/696 reads (25%) | catalogued as COSV100924958; called by muse, mutect2, varscan2
- WIPI2 | c.603C>T p.H201= | Silent (SNP) | VAF 195/712 reads (27%) | catalogued as COSV56592239; called by muse, mutect2, varscan2
